Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A952, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A952-01A (Primary Tumor).

(MIM/LL/TTTT)

ICD-O.3
Adenocarcinoma, mucinous,
endocervical type 8482/3
Site: Cervix NOS C53.9
JG 3/12/14

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

Biopsy of uterine cervix

- Mucinous adenocarcinoma of endocervical type, moderately differentiated and infiltrative.

Criteria	met 11/7/13	Yes	No
Diagnostic Discrepancy			✓
Tumor Malignancy History			✓

Source: NCI Genomic Data Commons file bca83f28-5a5e-498c-8e5a-9a1e8ddbdffb (TCGA-VS-A952.B7893751-3A8F-4FD8-996F-D8C93C108336.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).